Somatic mutation profile of tumor specimen C3N-02672-02 (aliquot CPT0187140006) from CPTAC case C3N-02672, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 60.4 years (22,056 days).
Specimen C3N-02672-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8612586-384f-4a12-a8c4-48b21a60e4b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02672-31 (Blood Derived Normal), aliquot CPT0187310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65412932-19f3-4b0e-b91f-b546c39a9e9f

The open-access MAF lists 820 somatic variants for this specimen: 578 protein-altering or splice-affecting, 150 silent, 92 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 493, Silent 150, Intron 41, Nonsense Mutation 39, RNA 22, Splice Site 18, Frame Shift Del 14, 3'UTR 14, 5'UTR 8, Frame Shift Ins 6, 5'Flank 6, Splice Region 4.

Variants (750 of 820; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- METTL14 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 89/264 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66310162, COSV66310354; called by muse, varscan2
- ABCA12 | c.2086C>A p.Q696K (on ENST00000272895 / NM_173076.3; = p.Q378K on NM_015657.3) | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs768468414; called by muse, mutect2, varscan2
- ADAM10 | c.1900G>T p.D634Y | Missense Mutation (SNP) | VAF 103/306 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV53051159; called by muse, mutect2, varscan2
- ADGRA1 | c.1242C>A p.H414Q | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.708); catalogued as COSV66925855; called by muse, mutect2, varscan2
- AFF2 | c.3864C>A p.S1288R | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53994231, COSV99663535; called by muse, mutect2, varscan2
- AFTPH | c.1693G>T p.G565C | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373997749; called by muse, mutect2, varscan2
- AK9 | c.4750G>A p.D1584N | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV101413978; called by muse, mutect2, varscan2
- ALDH1B1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.961); catalogued as rs1369468722, COSV66619750; called by muse, varscan2
- ALPK3 | c.2239C>T p.P747S | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.992); catalogued as COSV51929132; called by muse, mutect2, varscan2
- ANOS1 | c.542-1G>T p.X181_splice | Splice Site (SNP) | VAF 60/377 reads (16%) | catalogued as COSV52920901; called by muse, mutect2, varscan2
- APOL4 | c.421G>T p.V141F (on ENST00000352371 / NM_145660.2; = p.V138F on NM_030643.4) | Missense Mutation (SNP) | VAF 64/253 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV60653899; called by muse, mutect2, varscan2
- ATG4B | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs1256956340; called by muse, mutect2, varscan2
- ATP23 | c.353A>G p.H118R | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.812); catalogued as rs1168134452; called by muse, mutect2, varscan2
- ATRNL1 | c.1348+1G>T p.X450_splice | Splice Site (SNP) | VAF 17/87 reads (20%) | catalogued as COSV61803637; called by muse, varscan2
- AVPR1A | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs770889859; called by muse, varscan2
- BCOR | c.1210C>G p.Q404E | Missense Mutation (SNP) | VAF 112/486 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.043); catalogued as COSV100654331; called by muse, mutect2, varscan2
- BEND6 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.788); catalogued as rs201589903; called by muse, mutect2, varscan2
- BMX | c.1648G>A p.V550M | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1412977050; called by muse, mutect2, varscan2
- BRINP1 | c.1265G>T p.C422F | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56301868; called by muse, mutect2, varscan2
- BTBD8 | c.1097G>T p.C366F | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372147617; called by muse, mutect2, varscan2
- C16orf92 | c.74G>C p.R25P | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV54227198; called by muse, mutect2, varscan2
- C3orf20 | c.2038C>A p.R680S | Missense Mutation (SNP) | VAF 113/546 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.583); catalogued as COSV53786367; called by muse, mutect2, varscan2
- CACNA1E | c.2575G>A p.D859N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV62389547; called by muse, mutect2, varscan2
- CATIP | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs201618489; called by muse, mutect2, varscan2
- CATSPERE | c.2395A>G p.M799V | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs1302364609; called by muse, mutect2, varscan2
- CCDC138 | c.1293G>T p.W431C | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54566666; called by muse, mutect2, varscan2
- CCR5 | c.476C>A p.A159E | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs746300015; called by muse, mutect2, varscan2
- CCR6 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 32/145 reads (22%) | catalogued as COSV59475323; called by muse, mutect2, varscan2
- CDH9 | c.1081C>A p.L361M | Missense Mutation (SNP) | VAF 104/307 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as rs756492421, COSV99145698; called by muse, mutect2, varscan2
- CER1 | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 92/375 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs755968012, COSV66602948; called by muse, mutect2, varscan2
- CHAT | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 136/560 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.085); catalogued as rs751863010, COSV100340505; called by muse, mutect2, varscan2
- CHRNA1 | c.442G>T p.V148F (on ENST00000261007 / NM_001039523.3; = p.V123F on NM_000079.4) | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV53684978; called by muse, mutect2, varscan2
- CLIP1 | c.3220G>C p.E1074Q (on ENST00000620786 / NM_001247997.1; = p.E1063Q on NM_002956.2) | Missense Mutation (SNP) | VAF 73/315 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV56810459; called by muse, mutect2, varscan2
- CNTN3 | c.2575G>T p.G859* | Nonsense Mutation (SNP) | VAF 62/204 reads (30%) | catalogued as rs758435177; called by muse, mutect2, varscan2
- CNTNAP5 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 68/330 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV70484487; called by muse, mutect2, varscan2
- CNTRL | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1367330969; called by muse, mutect2, varscan2
- COL11A1 | c.780+1G>T p.X260_splice | Splice Site (SNP) | VAF 78/361 reads (22%) | catalogued as COSV62195095; called by muse, mutect2, varscan2
- COL4A1 | c.4451G>T p.G1484V | Missense Mutation (SNP) | VAF 69/328 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65423275; called by muse, mutect2, varscan2
- COLGALT1 | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs543254139, COSV99395097; called by muse, mutect2, varscan2
- CR1 | c.1016G>A p.R339H (on ENST00000367051; = p.R789H on NM_000651.6) | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0.031); catalogued as rs766277020, COSV100887969; called by muse, mutect2, varscan2
- CRB1 | c.3128A>G p.D1043G | Missense Mutation (SNP) | VAF 129/648 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as rs1357564499; called by muse, mutect2, varscan2
- CSMD2 | c.7438C>A p.L2480I | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.088); catalogued as COSV99589840; called by muse, mutect2, varscan2
- CXorf56 | c.422G>T p.S141I (on ENST00000536133 / NM_001170570.2; = p.S155I on NM_022101.4) | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs1416811032; called by muse, mutect2, varscan2
- DDX24 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770024404; called by muse, varscan2
- DDX54 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs139017196; called by muse, mutect2, varscan2
- DNAH6 | c.7463A>T p.K2488M | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs1202128063; called by muse, mutect2, varscan2
- DPEP1 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1463713392; called by muse, mutect2, varscan2
- DSEL | c.1569G>T p.K523N | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.1); catalogued as rs751165552; called by muse, mutect2, varscan2
- ELMO1 | c.1537G>T p.E513* | Nonsense Mutation (SNP) | VAF 60/256 reads (23%) | catalogued as COSV100163760, COSV100166617; called by muse, mutect2, varscan2
- ENPP3 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV100718143; called by muse, mutect2, varscan2
- ENSA | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 21/103 reads (20%) | catalogued as rs17847055; called by muse, mutect2, varscan2
- EP300 | c.3644T>A p.L1215* | Nonsense Mutation (SNP) | VAF 102/423 reads (24%) | catalogued as COSV54346458; called by muse, mutect2, varscan2
- EPHA3 | c.1698-1G>A p.X566_splice | Splice Site (SNP) | VAF 26/136 reads (19%) | catalogued as COSV60698561; called by muse, mutect2, varscan2
- EPHA3 | c.1698G>T p.R566S | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV60695787; called by muse, mutect2, varscan2
- EPHB3 | c.2098G>T p.V700L | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57808554; called by muse, mutect2, varscan2
- EPRS1 | c.3862G>T p.G1288W | Missense Mutation (SNP) | VAF 130/371 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100859457; called by muse, mutect2, varscan2
- EPRS1 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748899019; called by muse, mutect2, varscan2
- ESR1 | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as COSV52790184; called by muse, mutect2, varscan2
- EYA1 | c.1520C>A p.P507Q | Missense Mutation (SNP) | VAF 66/320 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58173602; called by muse, mutect2, varscan2
- EYS | c.6910G>T p.G2304W | Missense Mutation (SNP) | VAF 108/468 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65477064; called by muse, mutect2, varscan2
- EYS | c.1967C>A p.T656K | Missense Mutation (SNP) | VAF 78/409 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1257203855; called by muse, mutect2, varscan2
- EYS | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.36); catalogued as rs1562221891; called by muse, varscan2
- F10 | c.1270G>T p.V424F | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201301913, CM119603; called by muse, varscan2
- FAM133B | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764805216; called by muse, mutect2, varscan2
- FAM135B | c.3572C>T p.T1191M | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1473329880, COSV99421984; called by muse, mutect2, varscan2
- FAM151A | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 67/370 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV100156673; called by muse, mutect2, varscan2
- FAM47B | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100263899; called by muse, mutect2, varscan2
- FAT2 | c.7613C>A p.A2538D | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.227); catalogued as rs1561850233; called by muse, mutect2, varscan2
- FAT3 | c.4972C>T p.R1658C | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs201013393; called by muse, mutect2, varscan2
- FBN2 | c.3491G>T p.R1164L | Missense Mutation (SNP) | VAF 115/474 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1297011367, COSV52509331; called by muse, mutect2, varscan2
- FHIT | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100533577; called by muse, mutect2
- FLG | c.2930A>T p.Q977L | Missense Mutation (SNP) | VAF 158/884 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as rs752763503; called by muse, mutect2, varscan2
- FLNC | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 81/348 reads (23%) | catalogued as COSV100367740; called by muse, mutect2, varscan2
- GALNT14 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs1450914153, COSV61111297, COSV61112120; called by muse, varscan2
- GNL2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs1207041261; called by muse, mutect2, varscan2
- GRID1 | c.2437C>T p.L813F | Missense Mutation (SNP) | VAF 138/520 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV60042608; called by muse, mutect2, varscan2
- GRXCR1 | c.60C>G p.I20M | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs267600162, COSV67669835; called by muse, mutect2, varscan2
- GUCA1A | c.476G>C p.G159A | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM094674; called by muse, mutect2, varscan2
- HADHA | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 74/344 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66107711; called by muse, mutect2, varscan2
- HMCN2 | c.9233G>T p.G3078V | Missense Mutation (SNP) | VAF 92/522 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1260186594; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.64A>G p.K22E (on ENST00000354667 / NM_031243.3; = p.K10E on NM_002137.4) | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61158625; called by muse, mutect2, varscan2
- HOXA2 | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 48/285 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1438603716; called by muse, varscan2
- HSPA12A | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 101/386 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as rs781953547, COSV65021800; called by muse, mutect2, varscan2
- HYDIN | c.10083C>A p.F3361L | Missense Mutation (SNP) | VAF 51/341 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs774136704; called by muse, mutect2, varscan2
- HYOU1 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 41/375 reads (11%) | catalogued as rs781850918, COSV101345706; called by muse, mutect2, varscan2
- IARS2 | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.572); catalogued as rs1194945018; called by muse, varscan2
- ICE1 | c.5041A>G p.M1681V | Missense Mutation (SNP) | VAF 82/248 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1240860486; called by muse, mutect2, varscan2
- IDS | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM960862, COSV61711280; called by muse, mutect2, varscan2
- IFNAR2 | c.347A>T p.N116I | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs755290453, COSV59751553; called by muse, mutect2, varscan2
- IGKV1D-17 | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 80/397 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs1396712608; called by muse, varscan2
- IKZF1 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 55/307 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV58783363; called by muse, mutect2, varscan2
- IQCE | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV104396394; called by muse, varscan2
- KANSL1 | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.915); catalogued as rs770738115, COSV52273149; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KIF1A | c.871G>T p.G291* | Nonsense Mutation (SNP) | VAF 25/158 reads (16%) | catalogued as rs201050463; called by muse, mutect2, varscan2
- KIF5A | c.97A>T p.I33F | Missense Mutation (SNP) | VAF 84/346 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs540463538; called by muse, mutect2, varscan2
- KLHL1 | c.593C>A p.T198N | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as rs775583442, COSV64773405; called by muse, mutect2, varscan2
- KRT85 | c.1367del p.G456Afs*19 | Frame Shift Del (DEL) | VAF 114/577 reads (20%) | catalogued as rs749069701; called by mutect2, pindel, varscan2
- KRTAP13-3 | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV61878527, COSV61878844; called by muse, mutect2, varscan2
- LCT | c.3343del p.E1115Sfs*8 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as COSV51544352, COSV51548853; called by mutect2, pindel, varscan2
- LDLRAD3 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs752803367, COSV59683277; called by muse, mutect2, varscan2
- LINGO2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs770649517, COSV58061559; called by muse, mutect2, varscan2
- LPAR1 | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 107/265 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV62690501; called by muse, mutect2, varscan2
- LRP1B | c.4145C>G p.A1382G | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV67214464; called by muse, mutect2, varscan2
- LRP5 | c.4484C>T p.P1495L | Missense Mutation (SNP) | VAF 128/190 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs752755797, COSV99037174; ClinVar: uncertain significance; called by muse, varscan2
- LRRC26 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 119/638 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.059); catalogued as rs771013240; called by muse, mutect2, varscan2
- MAGEB17 | c.597C>A p.S199R | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV61557179; called by muse, mutect2, varscan2
- MFN2 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 144/710 reads (20%) | catalogued as COSV52424952; called by muse, mutect2, varscan2
- MME | c.521G>T p.W174L | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100852421, COSV64710678; called by muse, mutect2, varscan2
- MUC16 | c.26831G>T p.G8944V | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as rs752168296; called by muse, mutect2, varscan2
- MUC16 | c.8066C>T p.S2689L | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as rs760900707; called by muse, mutect2, varscan2
- MUC5B | c.14477C>A p.A4826D | Missense Mutation (SNP) | VAF 102/512 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.266); catalogued as rs1308758569; called by muse, mutect2, varscan2
- MYH2 | c.4735G>T p.D1579Y | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV55447835; called by muse, mutect2, varscan2
- MYOM3 | c.1752C>A p.S584R | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765243510, COSV58390302; called by muse, mutect2, varscan2
- NF1 | c.6820-1G>T p.X2274_splice (on ENST00000358273 / NM_001042492.3; = p.X2253_splice on NM_000267.3) | Splice Site (SNP) | VAF 29/123 reads (24%) | catalogued as CS1311545, CS134549, COSV62201674, COSV62227637; called by muse, mutect2, varscan2
- NPAP1 | c.3245C>A p.T1082N | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.184); catalogued as rs1366994547; called by muse, mutect2, varscan2
- NPHP3 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 95/317 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); catalogued as rs1337759677; called by muse, mutect2, varscan2
- OGDHL | c.1517C>A p.P506H | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65102171; called by muse, mutect2, varscan2
- OPRK1 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV55569888; called by muse, mutect2, varscan2
- OR14K1 | c.463C>A p.L155I | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51721094; called by muse, mutect2, varscan2
- OR14K1 | c.926G>T p.S309I | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV99315587; called by muse, mutect2, varscan2
- OR2G6 | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV58575380; called by muse, mutect2
- OR2K2 | c.842G>T p.G281V (on ENST00000374428; = p.G252V on NM_205859.2) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs960727704, COSV100235249; called by muse, mutect2, varscan2
- OR2K2 | c.841G>T p.G281W (on ENST00000374428; = p.G252W on NM_205859.2) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57016704; called by muse, mutect2, varscan2
- OR2T4 | c.578C>G p.P193R | Missense Mutation (SNP) | VAF 112/613 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63544276; called by muse, mutect2, varscan2
- OR4C3 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs747540397, COSV100167374; called by muse, mutect2, varscan2
- OR5AP2 | c.654G>T p.M218I | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV57257020; called by muse, mutect2, varscan2
- OR8H2 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV57943812; called by muse, mutect2, varscan2
- OR8J1 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV57320751; called by muse, mutect2, varscan2
- ORC5 | c.846G>T p.Q282H | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99857096; called by muse, mutect2, varscan2
- PAPPA2 | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100866875, COSV62772291; called by muse, mutect2, varscan2
- PCDHA4 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 115/497 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); catalogued as rs781991192; called by muse, mutect2, varscan2
- PCDHA5 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 193/863 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs782205967; called by muse, mutect2, varscan2
- PCDHB1 | c.2264A>G p.Y755C | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1554267514; called by muse, mutect2, varscan2
- PCLO | c.12814C>T p.R4272C | Missense Mutation (SNP) | VAF 86/348 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373739483; called by muse, mutect2, varscan2
- PLEKHM3 | c.1003C>G p.Q335E | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV66818138; called by muse, varscan2
- PNMA5 | c.488C>A p.S163* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV62625584; called by muse, mutect2, varscan2
- POLQ | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779118394; called by muse, mutect2, varscan2
- PPP1R16B | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55375214; called by muse, mutect2, varscan2
- PRRC2C | c.7606G>T p.G2536* (on ENST00000367742; = p.G2534* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 45/205 reads (22%) | catalogued as COSV58905211; called by muse, mutect2, varscan2
- PUSL1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 65/252 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs781550889; called by muse, varscan2
- RBM41 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.449); catalogued as COSV52564801; called by muse, mutect2, varscan2
- RELN | c.8274G>T p.K2758N | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV100632045; called by muse, mutect2, varscan2
- RELT | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 63/358 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as rs1428014277; called by muse, mutect2, varscan2
- RESF1 | c.4047G>T p.K1349N | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV57025617; called by muse, mutect2, varscan2
- RGPD3 | c.2752G>A p.V918M | Missense Mutation (SNP) | VAF 86/523 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as rs1455401899; called by muse, mutect2, varscan2
- RGS7 | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV58544846; called by mutect2, varscan2
- RIMS1 | c.1922del p.G641Vfs*3 | Frame Shift Del (DEL) | VAF 26/169 reads (15%) | catalogued as COSV53463076; called by mutect2, pindel, varscan2
- ROS1 | c.4903-1G>T p.X1635_splice | Splice Site (SNP) | VAF 22/76 reads (29%) | catalogued as COSV63858611, COSV63860312; called by muse, mutect2, varscan2
- RPGR | c.310+1G>T p.X104_splice | Splice Site (SNP) | VAF 76/369 reads (21%) | catalogued as CS021175, CS149275; called by muse, mutect2, varscan2
- RTL3 | c.1063A>T p.S355C | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV58186099; called by muse, mutect2, varscan2
- RXFP1 | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs746152132; called by muse, mutect2, varscan2
- SACS | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs1178823081; called by muse, mutect2, varscan2
- SCAF1 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as rs368120567; called by muse, mutect2, varscan2
- SCN3A | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV51817305; called by muse, mutect2, varscan2
- SERPINA3 | c.937C>A p.L313M | Missense Mutation (SNP) | VAF 101/496 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV67586341; called by muse, mutect2, varscan2
- SFSWAP | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as rs139185938, COSV99906030; called by muse, mutect2, varscan2
- SHANK1 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs954426144; called by muse, mutect2
- SHISA9 | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV69635096; called by muse, mutect2, varscan2
- SLIT1 | c.1426C>A p.R476S | Missense Mutation (SNP) | VAF 71/325 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56588240; called by muse, mutect2, varscan2
- SLITRK1 | c.911C>A p.A304D | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as COSV65675181; called by muse, mutect2, varscan2
- SMAD4 | c.249+1G>A p.X83_splice | Splice Site (SNP) | VAF 35/190 reads (18%) | catalogued as COSV61690758; called by muse, mutect2, varscan2
- SORCS1 | c.2954C>A p.P985Q | Missense Mutation (SNP) | VAF 55/227 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as COSV53860333; called by muse, mutect2, varscan2
- SPIB | c.482C>A p.S161Y | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.962); catalogued as rs1378680947; called by muse, mutect2, varscan2
- SPOCK3 | c.1194G>T p.W398C | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62738753, COSV62740175; called by muse, mutect2, varscan2
- SPTA1 | c.4704T>A p.C1568* | Nonsense Mutation (SNP) | VAF 83/480 reads (17%) | catalogued as rs560479426; called by muse, mutect2, varscan2
- SYNE3 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 76/321 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as COSV100516652; called by muse, mutect2, varscan2
- SYT6 | c.895C>A p.H299N (on ENST00000610222 / NM_001366225.1; = p.H214N on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/326 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV65773859, COSV65775696; called by muse, mutect2, varscan2
- TCTEX1D1 | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51075315; called by muse, mutect2, varscan2
- TET1 | c.891C>A p.Y297* | Nonsense Mutation (SNP) | VAF 61/282 reads (22%) | catalogued as COSV65387980; called by muse, mutect2, varscan2
- THSD1 | c.1499G>T p.R500L | Missense Mutation (SNP) | VAF 58/269 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.239); catalogued as rs1566959284, COSV51628438; called by muse, mutect2, varscan2
- TMC1 | c.1301A>G p.H434R | Missense Mutation (SNP) | VAF 182/543 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs375264737; called by muse, mutect2, varscan2
- TMEM168 | c.1900G>T p.D634Y | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57179329; called by muse, mutect2, varscan2
- TMEM200A | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.429); catalogued as COSV99760391; called by muse, mutect2, varscan2
- TMEM63B | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV52483686; called by muse, mutect2, varscan2
- TNN | c.1985G>T p.R662M | Missense Mutation (SNP) | VAF 120/726 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV53423337; called by muse, mutect2, varscan2
- TOPORS | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 143/601 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as CM1514215; called by muse, mutect2, varscan2
- TOX | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63850070; called by muse, mutect2, varscan2
- TRIM49C | c.229G>C p.A77P | Missense Mutation (SNP) | VAF 100/252 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99081629; called by muse, mutect2, varscan2
- TRIM58 | c.1231A>T p.I411F | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs771057446; called by muse, mutect2, varscan2
- TRIP12 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 58/322 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV99391219; called by muse, mutect2, varscan2
- TUBA3C | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 84/398 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.024); catalogued as rs1226855350, COSV67139322, COSV67139843; called by muse, mutect2, varscan2
- UGT2B4 | c.1350T>A p.H450Q | Missense Mutation (SNP) | VAF 77/256 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1312839815; called by muse, mutect2
- USH2A | c.14801A>T p.Y4934F | Missense Mutation (SNP) | VAF 179/532 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV56338881; called by muse, mutect2, varscan2
- VWF | c.7724G>T p.R2575L | Missense Mutation (SNP) | VAF 81/420 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as CM163332; called by muse, mutect2, varscan2
- WDR72 | c.2498C>T p.S833F | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV64746293; called by muse, mutect2, varscan2
- WWC1 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs749130729; called by muse, mutect2, varscan2
- ZNF248 | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs367729167; called by muse, mutect2, varscan2
- ZNF804A | c.1482G>T p.M494I | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100169189; called by muse, mutect2, varscan2
- ZNF99 | c.1037G>T p.C346F | Missense Mutation (SNP) | VAF 90/456 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101233719; called by muse, mutect2, varscan2
- AC127029.3 | c.678C>G p.D226E | Missense Mutation (SNP) | VAF 252/749 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ACTC1 | c.530T>A p.I177N | Missense Mutation (SNP) | VAF 75/300 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ADAMTS13 | c.2347G>T p.A783S | Missense Mutation (SNP) | VAF 62/327 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADCY2 | c.2877C>G p.H959Q | Missense Mutation (SNP) | VAF 121/311 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADCY4 | c.286G>T p.V96L | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ADCY7 | c.1901T>G p.L634R | Missense Mutation (SNP) | VAF 88/401 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ADGRV1 | c.14008G>T p.V4670F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, varscan2
- AHNAK2 | c.15166G>A p.G5056S | Missense Mutation (SNP) | VAF 61/318 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- AKAP6 | c.973G>T p.V325L | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALG13 | c.2174C>G p.P725R | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ALS2 | c.3033G>A p.M1011I | Missense Mutation (SNP) | VAF 100/427 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.1616G>T p.R539L | Missense Mutation (SNP) | VAF 192/501 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ANK2 | c.3897C>A p.F1299L | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD12 | c.5435C>G p.S1812C | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD34C | c.358del p.A120Lfs*8 | Frame Shift Del (DEL) | VAF 30/99 reads (30%) | called by mutect2, pindel, varscan2
- ANKRD36C | c.3396+1G>A p.X1132_splice | Splice Site (SNP) | VAF 18/130 reads (14%) | called by muse, mutect2, varscan2
- ANO3 | c.2809G>C p.D937H | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANOS1 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 60/387 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANXA6 | c.448A>T p.T150S | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP3B2 | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 79/247 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- APBB1 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- APP | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 69/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARID1B | c.3096G>T p.K1032N | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARMCX2 | c.1140T>A p.D380E | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- ARRB1 | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARSF | c.217T>A p.S73T | Missense Mutation (SNP) | VAF 104/407 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ARSF | c.407-1G>T p.X136_splice | Splice Site (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- ATP6AP1 | c.1073C>A p.A358D | Missense Mutation (SNP) | VAF 125/601 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- ATP6V1B1 | c.196G>T p.V66F | Missense Mutation (SNP) | VAF 111/543 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATXN7L2 | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- BAHCC1 | c.2813A>G p.Q938R | Missense Mutation (SNP) | VAF 72/524 reads (14%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BEST1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 175/514 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- BOD1L1 | c.8867C>T p.T2956I | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- BPIFA3 | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- BPIFC | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- BRINP1 | c.400A>T p.T134S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2
- BRWD3 | c.3692C>A p.A1231D | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRWD3 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- BUB1 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 30/174 reads (17%) | called by muse, mutect2, varscan2
- BUD23 | c.772C>G p.R258G | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1orf87 | c.698C>A p.T233K | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- C6orf201 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- C9 | c.697T>A p.S233T | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1H | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNB2 | c.1967T>A p.V656D (on ENST00000324631 / NM_201596.3; = p.V601D on NM_000724.4) | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CAGE1 | c.982T>C p.C328R (on ENST00000512086; = p.C192R on NM_205864.3) | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CAPZA3 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CATSPER4 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- CAV3 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 68/266 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- CCDC107 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 127/569 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CCDC120 | c.1441C>G p.L481V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC7 | c.1134+6A>G | Splice Region (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- CD2AP | c.1168A>T p.K390* | Nonsense Mutation (SNP) | VAF 63/198 reads (32%) | called by muse, mutect2, varscan2
- CDCP1 | c.1714A>T p.T572S | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH10 | c.439G>C p.V147L | Missense Mutation (SNP) | VAF 100/340 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- CES4A | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHPT1 | c.371_383delinsC p.C124_G128delinsS | In Frame Del (DEL) | VAF 16/110 reads (15%) | called by pindel, varscan2*
- CHRM4 | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 87/357 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CKMT2 | c.406C>G p.P136A | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CLASP2 | c.3469G>A p.D1157N (on ENST00000359576; = p.D1156N on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CLIP1 | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 65/298 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL21A1 | c.1729del p.D577Mfs*3 | Frame Shift Del (DEL) | VAF 28/145 reads (19%) | called by mutect2, pindel, varscan2
- COL4A6 | c.5035A>T p.T1679S | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL5A3 | c.1985G>T p.G662V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A3 | c.4486del p.Q1496Rfs*11 | Frame Shift Del (DEL) | VAF 103/438 reads (24%) | called by mutect2, pindel, varscan2
- COL6A5 | c.6226C>A p.L2076I (on ENST00000312481; = p.L2072I on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.018); called by mutect2, varscan2
- COPS9 | c.24G>C p.M8I (on ENST00000607357 / NM_001163424.2; = p.M29I on NM_138336.1) | Missense Mutation (SNP) | VAF 72/332 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- CPB1 | c.401C>A p.T134N | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPEB2 | c.2942G>T p.C981F | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CPED1 | c.2974G>A p.G992S | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPS1 | c.2938G>T p.G980C | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPSF2 | c.294G>C p.M98I | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- CROCC2 | c.3565C>T p.Q1189* | Nonsense Mutation (SNP) | VAF 69/349 reads (20%) | called by muse, mutect2, varscan2
- CSMD1 | c.6482C>G p.P2161R (on ENST00000520002; = p.P2160R on NM_033225.6) | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTCFL | c.1868C>A p.T623K | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP39A1 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 82/298 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, varscan2
- DEFB128 | c.55G>C p.A19P | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- DGAT2L6 | c.488G>T p.S163I | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DGKG | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DKC1 | c.117A>T p.K39N | Missense Mutation (SNP) | VAF 112/459 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- DLG3 | c.2184C>G p.I728M (on ENST00000374360 / NM_021120.4; = p.I423M on NM_020730.3) | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLG5 | c.2123G>T p.R708L | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMD | c.4390C>G p.P1464A | Missense Mutation (SNP) | VAF 85/344 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPYSL3 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DYSF | c.3140G>T p.R1047M | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EI24 | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 77/236 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF2AK1 | c.1481G>T p.C494F | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- EIF3A | c.1239G>T p.W413C | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ELP1 | c.3024G>T p.M1008I | Missense Mutation (SNP) | VAF 137/390 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENOX1 | c.1127_1128insC p.W376Cfs*6 | Frame Shift Ins (INS) | VAF 65/293 reads (22%) | called by mutect2, pindel, varscan2
- EPB41L2 | c.2175G>T p.K725N | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- EPHA6 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- ERO1A | c.716-1G>T p.X239_splice | Splice Site (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- F8 | c.1511C>A p.P504H | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FAM13A | c.425A>T p.Q142L | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM184B | c.474C>A p.Y158* | Nonsense Mutation (SNP) | VAF 52/231 reads (23%) | called by muse, mutect2, varscan2
- FAM83B | c.1411G>C p.D471H | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT4 | c.8095A>C p.S2699R | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBN1 | c.2924A>T p.H975L | Missense Mutation (SNP) | VAF 90/288 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBXO8 | c.330-2A>G p.X110_splice | Splice Site (SNP) | VAF 16/104 reads (15%) | called by muse, varscan2
- FCRL5 | c.25G>C p.V9L | Missense Mutation (SNP) | VAF 120/415 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FER1L6 | c.2797C>A p.P933T | Missense Mutation (SNP) | VAF 29/290 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- FGD1 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 76/313 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, varscan2
- FLG | c.9002C>T p.S3001F | Missense Mutation (SNP) | VAF 89/758 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- FOXS1 | c.921G>T p.Q307H | Missense Mutation (SNP) | VAF 83/324 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- FREM3 | c.2686A>G p.I896V | Missense Mutation (SNP) | VAF 56/285 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRMPD3 | c.4752C>G p.S1584R | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- FSIP2 | c.9133C>G p.P3045A | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSIP2 | c.14348C>T p.T4783I | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- GABBR2 | c.599C>A p.T200K | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GABRA5 | c.646G>C p.A216P | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- GABRG1 | c.431G>C p.W144S | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- GALNT10 | c.1522A>T p.R508* | Nonsense Mutation (SNP) | VAF 39/156 reads (25%) | called by muse, mutect2, varscan2
- GBE1 | c.1972G>C p.G658R | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGA1 | c.1762-1G>C p.X588_splice | Splice Site (SNP) | VAF 68/176 reads (39%) | called by muse, mutect2, varscan2
- GPR148 | c.487G>T p.G163W | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- GPRASP1 | c.2034G>T p.W678C | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- GRIA1 | c.2083G>A p.V695I | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRID2 | c.2638C>A p.R880S | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GRIK5 | c.1998T>A p.Y666* | Nonsense Mutation (SNP) | VAF 67/333 reads (20%) | called by muse, mutect2, varscan2
- GRIN2A | c.1066C>A p.Q356K | Missense Mutation (SNP) | VAF 228/610 reads (37%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- GXYLT2 | c.1085A>T p.N362I | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- HECW1 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 70/286 reads (24%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEMGN | c.927C>A p.D309E | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- HEMGN | c.9G>C p.L3F | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.04); called by muse, varscan2
- HHIPL1 | c.685G>T p.G229W | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- HMGA2 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HS3ST3B1 | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 88/339 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- HUWE1 | c.7549C>A p.P2517T | Missense Mutation (SNP) | VAF 52/275 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HYOU1 | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 43/386 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ICE1 | c.2713G>T p.D905Y | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- IGFN1 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 40/308 reads (13%) | called by muse, mutect2, varscan2
- IGHV1-3 | c.172C>G p.Q58E | Missense Mutation (SNP) | VAF 147/596 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- IGKV1D-17 | c.335A>C p.Q112P | Missense Mutation (SNP) | VAF 80/405 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, varscan2
- IGSF11 | c.1136G>C p.G379A (on ENST00000393775 / NM_001015887.3; = p.G378A on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/323 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL13RA1 | c.142G>C p.V48L | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL17RB | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 45/162 reads (28%) | called by muse, mutect2, varscan2
- IL1R1 | c.232A>T p.K78* | Nonsense Mutation (SNP) | VAF 48/231 reads (21%) | called by muse, mutect2, varscan2
- IL3 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- INPP5D | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INTS8 | c.2015A>C p.E672A | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IQCA1 | c.1876C>G p.R626G | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IQCE | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.996); called by muse, varscan2
- ITGA7 | c.1420G>T p.E474* (on ENST00000555728; = p.E430* on NM_002206.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 153/704 reads (22%) | called by muse, mutect2, varscan2
- JAK3 | c.2753del p.R918Pfs*53 | Frame Shift Del (DEL) | VAF 87/417 reads (21%) | called by mutect2, pindel, varscan2
- JCAD | c.1137G>C p.K379N | Missense Mutation (SNP) | VAF 102/375 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- KCNA6 | c.1180G>T p.V394F | Missense Mutation (SNP) | VAF 82/380 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNB2 | c.2664C>A p.H888Q | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- KCNK18 | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 80/345 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- KCTD15 | c.833A>T p.K278M | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KLHL4 | c.698T>A p.L233Q | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2C | c.2996G>T p.S999I | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- KRT23 | c.1141G>C p.G381R | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.243); called by muse, mutect2
- KRTAP19-6 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- L1CAM | c.679C>A p.L227I | Missense Mutation (SNP) | VAF 123/495 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LAMB4 | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 65/322 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- LARP4B | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LCN8 | c.115G>T p.V39F (on ENST00000612714 / NM_001345934.1; = p.V16F on NM_178469.3) | Missense Mutation (SNP) | VAF 88/465 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LIN28B | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LIN52 | c.105dup p.A36Cfs*2 | Frame Shift Ins (INS) | VAF 16/97 reads (16%) | called by mutect2, pindel, varscan2
- LRBA | c.6652A>T p.R2218* | Nonsense Mutation (SNP) | VAF 31/180 reads (17%) | called by muse, mutect2, varscan2
- LRRC7 | c.2354C>A p.P785H (on ENST00000651989 / NM_001370785.2; = p.P752H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRRN4 | c.327C>G p.N109K | Missense Mutation (SNP) | VAF 112/547 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LTA | c.79G>T p.V27F | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACF1 | c.4306G>T p.G1436C | Missense Mutation (SNP) | VAF 22/115 reads (19%) | called by muse, mutect2, varscan2
- MAGEB5 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MAGEE2 | c.725A>T p.Y242F | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- MAN2A1 | c.2822G>T p.G941V | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MBOAT1 | c.420-2A>G p.X140_splice | Splice Site (SNP) | VAF 40/160 reads (25%) | called by muse, mutect2, varscan2
- MED1 | c.1820T>A p.L607* | Nonsense Mutation (SNP) | VAF 67/268 reads (25%) | called by muse, mutect2, varscan2
- MEN1 | c.928-2A>T p.X310_splice | Splice Site (SNP) | VAF 128/443 reads (29%) | called by muse, mutect2, varscan2
- METTL14 | c.1014T>G p.C338W | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MGA | c.2444C>G p.S815* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- MKX | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MPPED2 | c.428A>T p.K143I | Missense Mutation (SNP) | VAF 65/317 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MTMR8 | c.2000C>A p.S667Y | Missense Mutation (SNP) | VAF 75/382 reads (20%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- MUC5AC | c.16139G>T p.W5380L | Missense Mutation (SNP) | VAF 58/275 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- MYH13 | c.4402C>A p.Q1468K | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- MYH13 | c.4401C>A p.S1467R | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- MYH2 | c.2107G>T p.G703C | Missense Mutation (SNP) | VAF 91/355 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MYH3 | c.544G>C p.G182R | Missense Mutation (SNP) | VAF 89/353 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYL7 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 34/231 reads (15%) | called by muse, mutect2, varscan2
- MYO1A | c.2485-1G>T p.X829_splice | Splice Site (SNP) | VAF 47/175 reads (27%) | called by muse, mutect2, varscan2
- MYO1C | c.465G>T p.Q155H (on ENST00000648651 / NM_001080779.2; = p.Q120H on NM_033375.5) | Missense Mutation (SNP) | VAF 88/333 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- MYO7A | c.6547G>C p.E2183Q | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYOM3 | c.400_401insA p.R134Qfs*58 | Frame Shift Ins (INS) | VAF 17/68 reads (25%) | called by mutect2, pindel*, varscan2
- NAV3 | c.2801C>T p.T934I | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, varscan2
- NAV3 | c.6596T>G p.I2199R (on ENST00000397909 / NM_001024383.2; = p.I2177R on NM_014903.6) | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NCAPH | c.1519A>T p.T507S | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NCAPH2 | c.352-1G>T p.X118_splice | Splice Site (SNP) | VAF 97/356 reads (27%) | called by muse, mutect2, varscan2
- NCOR2 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 96/452 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NDST4 | c.65G>C p.C22S | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.1); called by muse, mutect2
- NECAB1 | c.661C>A p.L221I | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NELL1 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 68/305 reads (22%) | called by muse, mutect2, varscan2
- NGEF | c.1143C>A p.L381= | Splice Region (SNP) | VAF 49/191 reads (26%) | called by muse, mutect2, varscan2
- NLGN1 | c.1880C>A p.T627N | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NLRP3 | c.2935C>A p.L979M | Missense Mutation (SNP) | VAF 59/300 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NLRP4 | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- NPTX2 | c.52_53insT p.Q18Lfs*8 | Frame Shift Ins (INS) | VAF 71/324 reads (22%) | called by mutect2, pindel, varscan2
- NPY5R | c.853C>A p.H285N | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- NUP214 | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 131/371 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- NUP98 | c.3974C>T p.T1325I (on ENST00000359171 / NM_001365126.1; = p.T1308I on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 101/442 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- NYNRIN | c.2967G>T p.M989I | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.10363G>T p.G3455C | Missense Mutation (SNP) | VAF 142/670 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- OCRL | c.2233C>A p.L745I | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OPRM1 | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- OR11L1 | c.692C>A p.T231N | Missense Mutation (SNP) | VAF 115/656 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- OR2B11 | c.212C>G p.S71C | Missense Mutation (SNP) | VAF 92/245 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- OR2L13 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 66/516 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- OR2L13 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 68/528 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- OR2T3 | c.507G>T p.M169I | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by mutect2, varscan2
- OR4L1 | c.739G>T p.V247F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR4Q3 | c.392G>T p.R131M | Missense Mutation (SNP) | VAF 49/355 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OR51E1 | c.744_745del p.A249Cfs*18 | Frame Shift Del (DEL) | VAF 38/187 reads (20%) | called by pindel, varscan2
- OR56A5 | c.609dup p.V204Cfs*10 | Frame Shift Ins (INS) | VAF 33/141 reads (23%) | called by mutect2, pindel, varscan2
- OR5D16 | c.309C>G p.F103L | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OR5K2 | c.367T>A p.Y123N | Missense Mutation (SNP) | VAF 63/273 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR7A10 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OTOF | c.4382A>T p.K1461I (on ENST00000272371 / NM_194248.3; = p.K694I on NM_004802.4) | Missense Mutation (SNP) | VAF 87/439 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OTOG | c.7650G>T p.E2550D | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OVCH1 | c.1435G>T p.V479L | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- PADI3 | c.974A>T p.E325V | Missense Mutation (SNP) | VAF 75/319 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PAPPA2 | c.3391G>T p.G1131* | Nonsense Mutation (SNP) | VAF 51/307 reads (17%) | called by muse, mutect2, varscan2
- PAX3 | c.1334C>G p.S445C | Missense Mutation (SNP) | VAF 86/406 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- PC | c.486G>T p.A162= | Splice Region (SNP) | VAF 498/798 reads (62%) | called by muse, mutect2, varscan2
- PCDH15 | c.4730C>A p.S1577* | Nonsense Mutation (SNP) | VAF 60/267 reads (22%) | called by muse, mutect2, varscan2
- PCDHA1 | c.2183C>A p.T728N | Missense Mutation (SNP) | VAF 85/397 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHAC1 | c.2059G>C p.A687P | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- PCNX1 | c.3568G>C p.D1190H | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PDE1A | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 77/355 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PDGFRB | c.2855C>A p.S952Y | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT tolerated (0.41); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDSS1 | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- PFDN6 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 67/292 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PHEX | c.1314G>T p.L438F | Missense Mutation (SNP) | VAF 56/313 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- PHEX | c.1315G>T p.V439F | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PHKA2 | c.1063C>A p.L355M | Missense Mutation (SNP) | VAF 119/450 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PIDD1 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3CG | c.1995G>C p.Q665H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIP4P1 | c.475G>T p.G159* | Nonsense Mutation (SNP) | VAF 62/303 reads (20%) | called by muse, mutect2, varscan2
- PKD1L1 | c.465C>G p.H155Q | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PLCL1 | c.2485C>G p.R829G | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- PLCXD2 | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 64/336 reads (19%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- PLXNB2 | c.5267A>G p.Y1756C | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- PMS1 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PNISR | c.1865G>T p.R622L | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- PNN | c.1062G>C p.E354D | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POF1B | c.1643C>A p.T548N | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POLQ | c.2983G>T p.D995Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLQ | c.1198G>T p.G400* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- POLR2F | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- POTED | c.1466C>A p.S489* | Nonsense Mutation (SNP) | VAF 30/132 reads (23%) | called by muse, mutect2, varscan2
- POTEJ | c.2986C>A p.P996T | Missense Mutation (SNP) | VAF 57/715 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- PQBP1 | c.469A>G p.R157G | Missense Mutation (SNP) | VAF 77/348 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PRAMEF6 | c.1241C>A p.P414H | Missense Mutation (SNP) | VAF 121/1282 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRDM16 | c.2459G>T p.R820L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.391); called by mutect2, varscan2
- PRDM16 | c.3558G>T p.L1186F | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- PRKCB | c.1414G>T p.V472L | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- PRKG1 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 38/178 reads (21%) | called by muse, mutect2, varscan2
- PRRG3 | c.374C>G p.A125G | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRSS12 | c.1457A>T p.Y486F | Missense Mutation (SNP) | VAF 135/407 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PSD4 | c.1432G>T p.G478C | Missense Mutation (SNP) | VAF 69/321 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- PSMD2 | c.1406A>G p.Y469C | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTH1R | c.1325A>T p.H442L | Missense Mutation (SNP) | VAF 103/428 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PTPN12 | c.1489G>T p.D497Y | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- RAB3GAP2 | c.2590G>A p.V864I | Missense Mutation (SNP) | VAF 63/367 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAG2 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 51/265 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAP1GDS1 | c.51C>A p.D17E (on ENST00000408927 / NM_001100427.2; = p.D18E on NM_021159.5) | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- RAP1GDS1 | c.875G>T p.G292V (on ENST00000408927 / NM_001100427.2; = p.G293V on NM_021159.5) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASEF | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- RELN | c.1967G>T p.G656V | Missense Mutation (SNP) | VAF 117/518 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RGS18 | c.440C>G p.A147G | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); called by muse, varscan2
- RGS7 | c.1363G>T p.G455* | Nonsense Mutation (SNP) | VAF 50/410 reads (12%) | called by muse, mutect2, varscan2
- RIMS2 | c.2016dup p.V673Cfs*14 (on ENST00000666250 / NM_001348490.2; = p.V481Cfs*14 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 17/96 reads (18%) | called by mutect2, pindel, varscan2
- RLIM | c.1785C>A p.H595Q | Missense Mutation (SNP) | VAF 76/295 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RTN1 | c.1244T>C p.L415P | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RUBCN | c.12G>C p.E4D | Missense Mutation (SNP) | VAF 119/475 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- RUNX3 | c.1060G>T p.D354Y | Missense Mutation (SNP) | VAF 106/448 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- RYR2 | c.5569C>A p.P1857T | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.8756A>T p.K2919I | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- S100A3 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SART3 | c.1306del p.V436Wfs*11 (on ENST00000228284; = p.V418Wfs*11 on NM_014706.4) | Frame Shift Del (DEL) | VAF 61/294 reads (21%) | called by mutect2, pindel, varscan2
- SBF2 | c.4294T>A p.Y1432N | Missense Mutation (SNP) | VAF 101/365 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCML4 | c.1105C>A p.L369I | Missense Mutation (SNP) | VAF 76/402 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SCN5A | c.520G>T p.V174F | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SDK1 | c.5326G>T p.V1776F | Missense Mutation (SNP) | VAF 115/496 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- SEC16B | c.1090G>T p.A364S | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- SECTM1 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- SELENOF | c.461T>C p.V154A | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SEMA3D | c.2130del p.L711* | Frame Shift Del (DEL) | VAF 104/406 reads (26%) | called by mutect2, pindel, varscan2
- SEMA5B | c.58del p.D20Ifs*7 | Frame Shift Del (DEL) | VAF 22/127 reads (17%) | called by mutect2, pindel, varscan2
- SGIP1 | c.1247C>A p.P416Q | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SH3TC2 | c.384del p.G129Afs*7 | Frame Shift Del (DEL) | VAF 62/280 reads (22%) | called by mutect2, pindel, varscan2
- SHISA9 | c.1198T>A p.L400M | Missense Mutation (SNP) | VAF 65/298 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- SHOC1 | c.1005C>A p.H335Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.031); called by muse, varscan2
- SIGLEC14 | c.725G>T p.S242I | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- SIGLEC7 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SIRT4 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- SLC22A2 | c.1063T>A p.W355R | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SLC24A5 | c.651C>G p.D217E | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC25A28 | c.971A>G p.Y324C | Missense Mutation (SNP) | VAF 102/406 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SLC25A43 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 59/283 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- SLC45A2 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 160/432 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC4A4 | c.2423G>T p.R808M (on ENST00000264485 / NM_001098484.3; = p.R764M on NM_003759.4) | Missense Mutation (SNP) | VAF 62/288 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC4A4 | c.2424G>T p.R808S (on ENST00000264485 / NM_001098484.3; = p.R764S on NM_003759.4) | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC7A11 | c.1190G>T p.W397L | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- SLC7A13 | c.303G>T p.L101F | Missense Mutation (SNP) | VAF 72/275 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- SLC9A9 | c.1412T>C p.F471S | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLFN11 | c.158T>C p.L53S | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLIT2 | c.3287A>T p.N1096I | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- SMG1 | c.8468A>T p.K2823M | Missense Mutation (SNP) | VAF 108/534 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- SMG1 | c.2716C>A p.L906M | Missense Mutation (SNP) | VAF 180/518 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SMG5 | c.271A>C p.I91L | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- SMG8 | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOX7 | c.781G>C p.A261P | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- STAB1 | c.482A>G p.Q161R | Missense Mutation (SNP) | VAF 78/337 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- STAB1 | c.4664C>A p.A1555D | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- STAC | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- STRN | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 68/306 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- STRN4 | c.2182A>T p.I728F | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STYXL2 | c.1690G>T p.G564* | Nonsense Mutation (SNP) | VAF 29/130 reads (22%) | called by muse, mutect2, varscan2
- SYNE2 | c.787+1G>T p.X263_splice | Splice Site (SNP) | VAF 59/259 reads (23%) | called by muse, mutect2, varscan2
- TAF1 | c.1969G>T p.D657Y (on ENST00000373790 / NM_138923.4; = p.D678Y on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/309 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TAF1L | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 85/314 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- TAF3 | c.928A>C p.K310Q | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TANC1 | c.3097G>T p.G1033C | Missense Mutation (SNP) | VAF 76/332 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- TBC1D2B | c.1233G>T p.Q411H | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TCAF2C | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 49/439 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCEAL9 | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- TCTN2 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- TDRD5 | c.2253G>A p.M751I | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TEKT4 | c.850C>G p.Q284E | Missense Mutation (SNP) | VAF 79/414 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM3 | c.6246T>A p.D2082E | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TEP1 | c.2578G>T p.D860Y | Missense Mutation (SNP) | VAF 78/300 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TEX15 | c.2602C>A p.H868N (on ENST00000256246; = p.H1251N on NM_001350162.2) | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TGM4 | c.1827C>A p.F609L | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2
- TIE1 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TKTL2 | c.1141G>C p.A381P | Missense Mutation (SNP) | VAF 124/625 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TLR8 | c.2264C>A p.A755E (on ENST00000218032 / NM_138636.5; = p.A773E on NM_016610.4) | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- TNXB | c.5051A>G p.K1684R (on ENST00000647633; = p.K1437R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/396 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TOPBP1 | c.2119G>C p.A707P | Missense Mutation (SNP) | VAF 95/392 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPTE | c.335A>G p.D112G (on ENST00000618007 / NM_199261.4; = p.D94G on NM_199259.4) | Missense Mutation (SNP) | VAF 29/321 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.233); called by muse, mutect2
- TRAV22 | c.20C>A p.A7D | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- TRHDE | c.64T>A p.S22T | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2
- TRIM22 | c.1291G>T p.V431F | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- TRIM67 | c.318C>G p.S106R | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSHZ3 | c.2666A>T p.Q889L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- TTBK1 | c.3008G>T p.R1003L | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTLL11 | c.2035A>G p.M679V | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- TTN | c.93344C>G p.T31115R (on ENST00000591111; = p.T23691R on NM_003319.4) | Missense Mutation (SNP) | VAF 90/438 reads (21%) | PolyPhen benign (0.361); called by muse, mutect2, varscan2
- TTN | c.15206T>A p.M5069K (on ENST00000591111; = p.M4142K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- TTYH2 | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 103/281 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- TUBA4A | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 86/355 reads (24%) | called by muse, mutect2, varscan2
- TXNRD1 | c.979T>C p.C327R (on ENST00000525566 / NM_001093771.3; = p.C229R on NM_003330.4) | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBQLN2 | c.1665del p.N556Tfs*40 | Frame Shift Del (DEL) | VAF 134/620 reads (22%) | called by mutect2, pindel, varscan2
- UMOD | c.939del p.W313Cfs*28 | Frame Shift Del (DEL) | VAF 230/791 reads (29%) | called by mutect2, pindel, varscan2
- UNC45B | c.1816G>T p.V606L | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- USP24 | c.6971A>T p.N2324I | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- USP29 | c.2135C>A p.T712N | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- VCAN | c.7021G>T p.A2341S | Missense Mutation (SNP) | VAF 119/455 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- VIRMA | c.3011C>A p.S1004* | Nonsense Mutation (SNP) | VAF 76/344 reads (22%) | called by muse, mutect2, varscan2
- VN1R4 | c.303G>T p.L101F | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- VPS13B | c.1240A>T p.S414C | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VPS8 | c.2122C>G p.L708V (on ENST00000625842 / NM_001349294.1; = p.L706V on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- WASH6P | c.1327G>C p.A443P | Missense Mutation (SNP) | VAF 122/978 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.085); called by muse, varscan2
- WDR64 | c.56A>G p.K19R | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR87 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 88/386 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WRN | c.2449-7T>C | Splice Region (SNP) | VAF 60/235 reads (26%) | called by muse, mutect2, varscan2
- WWC3 | c.1768G>C p.E590Q | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- XIRP2 | c.4356A>T p.E1452D (on ENST00000628543; = p.E1627D on NM_152381.6) | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- XIRP2 | c.7960G>T p.G2654C (on ENST00000628543; = p.G2829C on NM_152381.6) | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZAN | c.4874_4882del p.R1625_A1627del | In Frame Del (DEL) | VAF 29/173 reads (17%) | called by mutect2, pindel
- ZBTB34 | c.1268C>T p.T423I | Missense Mutation (SNP) | VAF 149/375 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZDHHC4 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 81/392 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZFHX4 | c.7633C>T p.P2545S | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZMYM6 | c.24A>T p.E8D | Missense Mutation (SNP) | VAF 56/264 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF208 | c.2608T>A p.Y870N | Missense Mutation (SNP) | VAF 75/388 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ZNF208 | c.898C>A p.L300I | Missense Mutation (SNP) | VAF 88/344 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, varscan2
- ZNF280C | c.1679C>G p.S560C | Missense Mutation (SNP) | VAF 65/317 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- ZNF462 | c.5438A>T p.D1813V | Missense Mutation (SNP) | VAF 52/301 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- ZNF574 | c.2476G>T p.D826Y | Missense Mutation (SNP) | VAF 77/379 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ZNF614 | c.1189A>T p.K397* | Nonsense Mutation (SNP) | VAF 73/225 reads (32%) | called by muse, mutect2, varscan2
- ZNF638 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF676 | c.377A>T p.H126L (on ENST00000650058; = p.H94L on NM_001001411.3) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF676 | c.376C>T p.H126Y (on ENST00000650058; = p.H94Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ZNF704 | c.1162G>T p.V388L | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF804A | c.3172C>A p.P1058T | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- ZNF853 | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 89/438 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZXDA | c.1880G>T p.G627V | Missense Mutation (SNP) | VAF 78/470 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZXDA | c.881G>T p.S294I | Missense Mutation (SNP) | VAF 65/287 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- A4GALT | c.516C>T p.P172= | Silent (SNP) | VAF 141/613 reads (23%) | catalogued as rs576019459; called by muse, mutect2, varscan2
- ADAD1 | c.1131T>A p.V377= | Silent (SNP) | VAF 105/285 reads (37%) | called by muse, mutect2, varscan2
- ADGRG4 | c.1431T>A p.A477= | Silent (SNP) | VAF 31/129 reads (24%) | called by muse, mutect2, varscan2
- ADGRL3 | c.2010A>T p.L670= (on ENST00000506720 / NM_001322402.2; = p.L602= on NM_015236.6) | Silent (SNP) | VAF 72/263 reads (27%) | called by muse, mutect2, varscan2
- ADGRV1 | c.15498G>T p.T5166= | Silent (SNP) | VAF 95/393 reads (24%) | catalogued as COSV67983516; called by muse, mutect2, varscan2
- ADRB2 | c.852C>A p.L284= | Silent (SNP) | VAF 105/472 reads (22%) | called by muse, mutect2, varscan2
- ALS2 | c.2874G>C p.T958= | Silent (SNP) | VAF 77/315 reads (24%) | catalogued as COSV51890834; called by muse, mutect2, varscan2
- ALS2 | c.168G>T p.L56= | Silent (SNP) | VAF 77/391 reads (20%) | called by muse, mutect2, varscan2
- ANK2 | c.6105G>A p.P2035= | Silent (SNP) | VAF 75/180 reads (42%) | catalogued as rs757880191, COSV100002412; called by muse, mutect2, varscan2
- ANKRD27 | c.2286C>T p.L762= | Silent (SNP) | VAF 60/262 reads (23%) | catalogued as rs1017929684; called by muse, mutect2
- APEX2 | c.447C>A p.T149= | Silent (SNP) | VAF 57/227 reads (25%) | called by muse, mutect2, varscan2
- ARID5B | c.1749A>C p.T583= | Silent (SNP) | VAF 27/119 reads (23%) | called by muse, mutect2, varscan2
- ARX | c.1518C>A p.P506= | Silent (SNP) | VAF 30/128 reads (23%) | called by muse, mutect2, varscan2
- ATXN1 | c.999G>T p.R333= | Silent (SNP) | VAF 64/238 reads (27%) | called by muse, mutect2, varscan2
- BBS9 | c.2587C>T p.L863= (on ENST00000242067 / NM_001348036.1; = p.L823= on NM_014451.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/266 reads (17%) | called by muse, mutect2, varscan2
- BUB1 | c.327G>T p.L109= | Silent (SNP) | VAF 30/176 reads (17%) | called by muse, mutect2, varscan2
- CACNA1A | c.1812C>A p.V604= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV64198319; called by muse, mutect2, varscan2
- CACNA1C | c.63G>T p.G21= | Silent (SNP) | VAF 20/79 reads (25%) | called by muse, varscan2
- CACNA1C | c.1017C>A p.P339= | Silent (SNP) | VAF 71/310 reads (23%) | called by muse, mutect2, varscan2
- CACNA1E | c.2574G>T p.G858= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV62405469; called by muse, mutect2, varscan2
- CCNA1 | c.393C>A p.P131= | Silent (SNP) | VAF 59/295 reads (20%) | called by muse, mutect2, varscan2
- CCNE1 | c.522C>T p.D174= | Silent (SNP) | VAF 25/124 reads (20%) | called by muse, mutect2, varscan2
- CDHR1 | c.2376G>T p.P792= | Silent (SNP) | VAF 74/334 reads (22%) | called by muse, mutect2, varscan2
- CDX4 | c.63T>A p.P21= | Silent (SNP) | VAF 62/247 reads (25%) | called by muse, mutect2, varscan2
- CEP170 | c.3987A>G p.S1329= | Silent (SNP) | VAF 23/140 reads (16%) | called by muse, mutect2, varscan2
- CFAP94 | c.576T>C p.S192= (on ENST00000320267 / NM_001352064.2; = p.S198= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as rs1179588665; called by muse, mutect2, varscan2
- CLEC9A | c.684G>A p.K228= | Silent (SNP) | VAF 31/155 reads (20%) | called by muse, mutect2, varscan2
- CLSPN | c.390T>A p.P130= | Silent (SNP) | VAF 52/280 reads (19%) | called by muse, mutect2, varscan2
- CMYA5 | c.9978A>G p.T3326= | Silent (SNP) | VAF 64/307 reads (21%) | called by muse, mutect2, varscan2
- COLGALT1 | c.1660C>T p.L554= | Silent (SNP) | VAF 79/313 reads (25%) | called by muse, mutect2, varscan2
- CRB2 | c.1539C>A p.A513= | Silent (SNP) | VAF 66/307 reads (21%) | catalogued as rs757677524; called by muse, mutect2, varscan2
- CSMD3 | c.8997C>G p.G2999= (on ENST00000297405 / NM_001363185.1; = p.G2830= on NM_052900.3) | Silent (SNP) | VAF 66/343 reads (19%) | catalogued as COSV52336724; called by muse, mutect2, varscan2
- CSMD3 | c.987A>T p.T329= | Silent (SNP) | VAF 35/176 reads (20%) | called by muse, mutect2, varscan2
- CT47B1 | c.594G>A p.E198= | Silent (SNP) | VAF 179/728 reads (25%) | catalogued as COSV100989048; called by muse, mutect2, varscan2
- CYP26B1 | c.1260G>T p.A420= | Silent (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- CYP2W1 | c.762C>T p.H254= | Silent (SNP) | VAF 43/174 reads (25%) | catalogued as rs145537266, COSV58271528; called by muse, mutect2, varscan2
- DDX10 | c.477G>A p.E159= | Silent (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- DHX30 | c.570G>A p.E190= (on ENST00000445061 / NM_138615.3; = p.E151= on NM_014966.3) | Silent (SNP) | VAF 107/440 reads (24%) | called by muse, mutect2, varscan2
- DNTT | c.1317C>T p.Y439= | Silent (SNP) | VAF 53/198 reads (27%) | catalogued as rs757253904, COSV64523164; called by muse, mutect2, varscan2
- DSCAML1 | c.891G>T p.V297= (on ENST00000321322; = p.V237= on NM_020693.4) | Silent (SNP) | VAF 54/183 reads (30%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.11355G>C p.V3785= | Silent (SNP) | VAF 36/314 reads (11%) | called by muse, mutect2, varscan2
- FAM214A | c.3066C>T p.L1022= | Silent (SNP) | VAF 34/111 reads (31%) | called by muse, mutect2, varscan2
- FAM47C | c.933C>A p.P311= | Silent (SNP) | VAF 126/502 reads (25%) | catalogued as COSV63728230; called by muse, mutect2, varscan2
- FAT2 | c.7614C>A p.A2538= | Silent (SNP) | VAF 30/152 reads (20%) | called by muse, mutect2, varscan2
- FATE1 | c.438G>T p.R146= | Silent (SNP) | VAF 95/332 reads (29%) | called by muse, mutect2, varscan2
- FCGBP | c.9426G>A p.R3142= | Silent (SNP) | VAF 40/516 reads (8%) | catalogued as rs779225255; called by muse, mutect2
- FCGBP | c.5823G>A p.R1941= | Silent (SNP) | VAF 40/495 reads (8%) | catalogued as rs1359962743; called by muse, mutect2
- FER1L6 | c.2796C>A p.P932= | Silent (SNP) | VAF 30/291 reads (10%) | catalogued as COSV67548490; called by muse, mutect2
- FGD1 | c.132G>C p.A44= | Silent (SNP) | VAF 60/282 reads (21%) | catalogued as COSV64309599; called by muse, varscan2
- FLG | c.9003T>A p.S3001= | Silent (SNP) | VAF 90/756 reads (12%) | catalogued as COSV64249245; called by muse, mutect2, varscan2
- FLT4 | c.444C>G p.V148= | Silent (SNP) | VAF 74/369 reads (20%) | called by muse, mutect2, varscan2
- FTSJ1 | c.912C>A p.P304= | Silent (SNP) | VAF 34/128 reads (27%) | called by muse, mutect2, varscan2
- GEMIN5 | c.3312C>G p.A1104= | Silent (SNP) | VAF 110/420 reads (26%) | called by muse, mutect2, varscan2
- GOLGA6L10 | c.336C>T p.I112= | Silent (SNP) | VAF 56/424 reads (13%) | called by mutect2, varscan2
- GPR158 | c.1353C>A p.G451= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs772207630; called by muse, mutect2, varscan2
- GRM6 | c.1974C>T p.G658= | Silent (SNP) | VAF 103/432 reads (24%) | catalogued as COSV51441424; called by muse, mutect2, varscan2
- HBG2 | c.207G>T p.L69= | Silent (SNP) | VAF 196/1555 reads (13%) | called by muse, mutect2, varscan2
- HCN1 | c.1908C>A p.I636= | Silent (SNP) | VAF 148/900 reads (16%) | catalogued as COSV57492543, COSV57537064; called by muse, mutect2, varscan2
- HOMER1 | c.831C>T p.A277= | Silent (SNP) | VAF 22/112 reads (20%) | called by muse, mutect2, varscan2
- HSPA12A | c.1599G>T p.S533= | Silent (SNP) | VAF 59/217 reads (27%) | catalogued as COSV65022548; called by muse, mutect2, varscan2
- IGFN1 | c.57G>T p.V19= | Silent (SNP) | VAF 40/307 reads (13%) | called by muse, mutect2, varscan2
- IQCE | c.57A>C p.A19= | Silent (SNP) | VAF 24/225 reads (11%) | called by muse, varscan2
- IRAK2 | c.1407C>T p.D469= | Silent (SNP) | VAF 85/441 reads (19%) | called by muse, mutect2, varscan2
- KCNH4 | c.2076T>A p.S692= | Silent (SNP) | VAF 54/253 reads (21%) | called by muse, mutect2, varscan2
- KLHL1 | c.594C>A p.T198= | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as COSV64784511; called by muse, mutect2, varscan2
- KRBOX4 | c.6C>A p.A2= | Silent (SNP) | VAF 11/161 reads (7%) | called by muse, mutect2
- KRTAP1-3 | c.228C>T p.C76= | Silent (SNP) | VAF 186/882 reads (21%) | catalogued as rs1439345506; called by muse, mutect2, varscan2
- LIMA1 | c.663A>T p.G221= | Silent (SNP) | VAF 39/241 reads (16%) | called by muse, mutect2, varscan2
- LRP4 | c.612C>T p.I204= | Silent (SNP) | VAF 72/265 reads (27%) | catalogued as rs757902891, COSV101066384; called by muse, mutect2, varscan2
- MAGED1 | c.2178C>A p.P726= | Silent (SNP) | VAF 59/211 reads (28%) | catalogued as COSV100431669; called by muse, mutect2, varscan2
- MARCKS | c.273C>A p.A91= | Silent (SNP) | VAF 46/191 reads (24%) | called by muse, mutect2, varscan2
- MGAT3 | c.1302C>A p.S434= | Silent (SNP) | VAF 133/548 reads (24%) | catalogued as COSV57866122; called by muse, mutect2, varscan2
- MUC2 | c.3418C>A p.R1140= | Silent (SNP) | VAF 22/151 reads (15%) | called by muse, mutect2, varscan2
- MUC5B | c.14478C>A p.A4826= | Silent (SNP) | VAF 107/517 reads (21%) | called by muse, mutect2, varscan2
- MYBPC3 | c.1593G>C p.G531= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs727503199, COSV57024287; called by muse, mutect2, varscan2
- MYF6 | c.403C>A p.R135= | Silent (SNP) | VAF 53/254 reads (21%) | catalogued as COSV57350507; called by muse, mutect2, varscan2
- MYO1H | c.684C>T p.G228= | Silent (SNP) | VAF 41/213 reads (19%) | catalogued as rs142785493; called by muse, mutect2, varscan2
- NCOA3 | c.381G>T p.V127= | Silent (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- NFE2L3 | c.1977C>G p.P659= | Silent (SNP) | VAF 42/193 reads (22%) | catalogued as COSV50235506; called by muse, mutect2, varscan2
- NKD2 | c.942C>G p.A314= | Silent (SNP) | VAF 87/230 reads (38%) | called by muse, mutect2, varscan2
- NOTCH3 | c.5082G>T p.R1694= | Silent (SNP) | VAF 114/472 reads (24%) | called by muse, mutect2, varscan2
- NTNG1 | c.165G>C p.T55= | Silent (SNP) | VAF 57/250 reads (23%) | catalogued as COSV99640065; called by muse, mutect2, varscan2
- OCA2 | c.1092G>T p.L364= | Silent (SNP) | VAF 94/370 reads (25%) | called by muse, mutect2, varscan2
- OR2A25 | c.408C>A p.T136= | Silent (SNP) | VAF 124/576 reads (22%) | called by muse, mutect2, varscan2
- OR2A7 | c.111C>A p.T37= | Silent (SNP) | VAF 28/299 reads (9%) | called by muse, mutect2, varscan2
- OR2T2 | c.105C>A p.I35= | Silent (SNP) | VAF 140/1852 reads (8%) | catalogued as rs528774471, COSV61618126, COSV61618913; called by muse, mutect2
- OR4L1 | c.738G>T p.V246= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV59851033; called by muse, mutect2, varscan2
- OR4S1 | c.846T>A p.P282= | Silent (SNP) | VAF 42/186 reads (23%) | called by muse, mutect2, varscan2
- OR51S1 | c.267G>C p.L89= | Silent (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- OR6K2 | c.174C>A p.P58= | Silent (SNP) | VAF 65/291 reads (22%) | catalogued as COSV62743365; called by muse, mutect2, varscan2
- OTUD6A | c.522C>A p.T174= | Silent (SNP) | VAF 70/308 reads (23%) | catalogued as COSV57973230; called by muse, mutect2, varscan2
- OXA1L | c.831C>T p.L277= (on ENST00000285848; = p.L217= on NM_005015.5) | Silent (SNP) | VAF 30/177 reads (17%) | called by muse, mutect2, varscan2
- PCDH12 | c.2580G>A p.R860= | Silent (SNP) | VAF 114/506 reads (23%) | called by muse, mutect2, varscan2
- PCDH15 | c.4731A>G p.S1577= | Silent (SNP) | VAF 58/269 reads (22%) | called by muse, mutect2, varscan2
- PCDH8 | c.2979G>T p.L993= | Silent (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- PCDHB16 | c.678T>A p.A226= | Silent (SNP) | VAF 41/206 reads (20%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.1000C>T p.L334= | Silent (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.1191A>T p.S397= | Silent (SNP) | VAF 81/349 reads (23%) | called by muse, mutect2, varscan2
- PDZD4 | c.1510C>A p.R504= | Silent (SNP) | VAF 43/144 reads (30%) | called by muse, mutect2, varscan2
- PI15 | c.597T>A p.S199= | Silent (SNP) | VAF 37/232 reads (16%) | called by muse, mutect2, varscan2
- PIGT | c.1566C>T p.F522= | Silent (SNP) | VAF 81/419 reads (19%) | called by muse, mutect2, varscan2
- PIK3CG | c.973C>T p.L325= | Silent (SNP) | VAF 52/253 reads (21%) | called by muse, mutect2, varscan2
- PIP | c.406C>A p.R136= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as rs747198857, COSV52119974; called by muse, mutect2, varscan2
- PIP5K1C | c.1578G>T p.T526= | Silent (SNP) | VAF 77/363 reads (21%) | catalogued as COSV58953367; called by muse, mutect2, varscan2
- PLEKHM3 | c.1035G>T p.G345= | Silent (SNP) | VAF 45/198 reads (23%) | called by muse, varscan2
- PLXNB3 | c.1941G>C p.P647= | Silent (SNP) | VAF 105/422 reads (25%) | catalogued as COSV100738102; called by muse, mutect2, varscan2
- PLXNB3 | c.2247C>A p.A749= | Silent (SNP) | VAF 39/170 reads (23%) | called by muse, mutect2, varscan2
- PRKAA2 | c.747G>T p.L249= | Silent (SNP) | VAF 38/167 reads (23%) | catalogued as rs138611495; called by muse, mutect2, varscan2
- PROM1 | c.1473C>T p.F491= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- PRR33 | c.1137C>A p.P379= | Silent (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- PTPN12 | c.1488G>T p.V496= | Silent (SNP) | VAF 25/133 reads (19%) | called by muse, mutect2, varscan2
- PTPRR | c.1395G>T p.T465= | Silent (SNP) | VAF 34/169 reads (20%) | catalogued as rs565130853, COSV51725656, COSV51743207; called by muse, mutect2, varscan2
- PURG | c.270C>A p.V90= | Silent (SNP) | VAF 57/230 reads (25%) | called by muse, mutect2, varscan2
- REG1B | c.126C>A p.A42= | Silent (SNP) | VAF 100/486 reads (21%) | catalogued as rs1273593199; called by muse, mutect2, varscan2
- RELN | c.918C>G p.V306= | Silent (SNP) | VAF 81/403 reads (20%) | called by muse, mutect2, varscan2
- SCAF1 | c.318C>T p.P106= | Silent (SNP) | VAF 44/205 reads (21%) | called by muse, mutect2, varscan2
- SCN3A | c.5313G>A p.L1771= | Silent (SNP) | VAF 100/446 reads (22%) | catalogued as rs1169477357; called by muse, mutect2, varscan2
- SCN5A | c.2013C>T p.S671= | Silent (SNP) | VAF 50/209 reads (24%) | catalogued as rs751050999, COSV61135167; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SFSWAP | c.1383C>T p.D461= | Silent (SNP) | VAF 22/144 reads (15%) | called by muse, mutect2, varscan2
- SHCBP1L | c.1032C>A p.V344= | Silent (SNP) | VAF 82/205 reads (40%) | called by muse, mutect2, varscan2
- SIRPB1 | c.852G>C p.L284= | Silent (SNP) | VAF 31/183 reads (17%) | called by muse, mutect2, varscan2
- SIRPB1 | c.123C>G p.S41= | Silent (SNP) | VAF 82/352 reads (23%) | catalogued as COSV53539270; called by muse, mutect2, varscan2
- SKAP2 | c.261A>T p.S87= | Silent (SNP) | VAF 71/286 reads (25%) | called by muse, mutect2, varscan2
- SLC6A14 | c.1632A>T p.S544= | Silent (SNP) | VAF 41/156 reads (26%) | catalogued as COSV64141455; called by muse, mutect2, varscan2
- SLC6A7 | c.1515G>T p.L505= | Silent (SNP) | VAF 29/170 reads (17%) | catalogued as rs1322982009, COSV100046667; called by muse, mutect2, varscan2
- SORCS1 | c.2607G>A p.V869= | Silent (SNP) | VAF 37/137 reads (27%) | called by muse, mutect2, varscan2
- SOWAHA | c.720C>T p.R240= | Silent (SNP) | VAF 121/467 reads (26%) | called by muse, mutect2, varscan2
- SPANXD | c.144G>T p.S48= | Silent (SNP) | VAF 113/599 reads (19%) | catalogued as rs142384328, COSV65153085; called by muse, mutect2, varscan2
- SPPL2C | c.426C>G p.P142= | Silent (SNP) | VAF 68/293 reads (23%) | called by muse, mutect2, varscan2
- SRCIN1 | c.2451G>A p.L817= (on ENST00000621492; = p.L783= on NM_025248.3) | Silent (SNP) | VAF 89/429 reads (21%) | called by muse, mutect2, varscan2
- STK31 | c.138A>G p.T46= | Silent (SNP) | VAF 41/151 reads (27%) | catalogued as rs377643324; called by muse, mutect2, varscan2
- TCEAL5 | c.75G>A p.E25= | Silent (SNP) | VAF 30/143 reads (21%) | called by muse, mutect2, varscan2
- TESPA1 | c.114G>A p.Q38= | Silent (SNP) | VAF 35/186 reads (19%) | called by muse, mutect2, varscan2
- TG | c.5718C>G p.L1906= | Silent (SNP) | VAF 93/395 reads (24%) | called by muse, mutect2, varscan2
- TLL1 | c.639C>T p.C213= | Silent (SNP) | VAF 104/347 reads (30%) | catalogued as rs755923669; called by muse, mutect2, varscan2
- TMC4 | c.1290G>C p.L430= (on ENST00000617472 / NM_001145303.3; = p.L424= on NM_144686.4) | Silent (SNP) | VAF 67/257 reads (26%) | called by muse, mutect2, varscan2
- TMEM132D | c.459C>A p.G153= | Silent (SNP) | VAF 64/323 reads (20%) | catalogued as COSV70619797; called by muse, mutect2, varscan2
- TPSD1 | c.504C>T p.G168= | Silent (SNP) | VAF 74/206 reads (36%) | catalogued as rs201223052, COSV99273838; called by muse, varscan2
- TRAV13-2 | c.150A>T p.S50= | Silent (SNP) | VAF 59/255 reads (23%) | called by muse, mutect2, varscan2
- TRIM11 | c.1305G>T p.S435= | Silent (SNP) | VAF 61/377 reads (16%) | catalogued as COSV99489092; called by muse, mutect2, varscan2
- TTN | c.92082T>A p.P30694= (on ENST00000591111; = p.P23270= on NM_003319.4) | Silent (SNP) | VAF 31/146 reads (21%) | catalogued as rs1239361545; called by muse, mutect2, varscan2
- UGT2B15 | c.114T>C p.N38= | Silent (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- URB2 | c.3531A>T p.A1177= | Silent (SNP) | VAF 24/156 reads (15%) | called by muse, mutect2, varscan2
- WDR87 | c.216C>T p.S72= | Silent (SNP) | VAF 92/394 reads (23%) | catalogued as rs1338930149; called by muse, mutect2, varscan2
- WNK3 | c.4584A>T p.I1528= | Silent (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2
- YTHDC1 | c.1287G>A p.V429= (on ENST00000344157 / NM_001031732.4; = p.V411= on NM_133370.4) | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as COSV60010674; called by muse, mutect2, varscan2
- ZDHHC8 | c.1629C>T p.N543= | Silent (SNP) | VAF 61/269 reads (23%) | catalogued as rs1456758998; called by muse, mutect2, varscan2
- ZFHX4 | c.1542G>T p.V514= | Silent (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- ZNF322 | c.231G>A p.E77= | Silent (SNP) | VAF 32/184 reads (17%) | called by mutect2, varscan2
- ZNF536 | c.1296C>G p.S432= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV62837019; called by muse, mutect2, varscan2
- ABCA11P | n.1034G>T | RNA (SNP) | VAF 62/334 reads (19%) | called by muse, mutect2, varscan2
- AC078880.2 | n.367C>T | RNA (SNP) | VAF 47/203 reads (23%) | called by muse, mutect2, varscan2
- AC140125.2 | n.569C>A | RNA (SNP) | VAF 29/140 reads (21%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-8966A>T | Intron (SNP) | VAF 173/758 reads (23%) | called by muse, mutect2, varscan2
- ADAM6 | n.719G>A | RNA (SNP) | VAF 45/187 reads (24%) | catalogued as rs1555411042; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1046+2955C>T | Intron (SNP) | VAF 71/245 reads (29%) | called by muse, mutect2, varscan2
- ANKRD20A5P | n.227C>G | RNA (SNP) | VAF 102/322 reads (32%) | called by muse, mutect2, varscan2
- ANKRD33 | c.263-86C>T | Intron (SNP) | VAF 50/190 reads (26%) | called by muse, mutect2, varscan2
- ANXA2P2 | n.159G>T | RNA (SNP) | VAF 83/356 reads (23%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915937 C>A | 5'Flank (SNP) | VAF 38/162 reads (23%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+441G>A | Intron (SNP) | VAF 35/130 reads (27%) | called by muse, mutect2, varscan2
- ATG4B | chr2:241637680 C>G | 5'Flank (SNP) | VAF 121/438 reads (28%) | called by muse, mutect2, varscan2
- BNC2 | c.2640-1620G>T | Intron (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- CACNG2 | c.-33G>C | 5'UTR (SNP) | VAF 66/282 reads (23%) | called by muse, mutect2, varscan2
- CACNG4 | c.*819G>T | 3'UTR (SNP) | VAF 159/458 reads (35%) | called by muse, mutect2, varscan2
- CCDC18 | c.-3+178G>T | Intron (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- CCDC34 | c.*21C>T | 3'UTR (SNP) | VAF 36/171 reads (21%) | called by muse, varscan2
- CDK5RAP3 | c.*145G>T | 3'UTR (SNP) | VAF 72/330 reads (22%) | called by muse, mutect2, varscan2
- CFAP300 | c.-1G>T | 5'UTR (SNP) | VAF 40/1028 reads (4%) | catalogued as COSV101462467; called by muse, mutect2
- CFAP91 | c.1680+87T>G | Intron (SNP) | VAF 28/103 reads (27%) | called by muse, varscan2
- CLASRP | c.*26C>A | 3'UTR (SNP) | VAF 4/26 reads (15%) | catalogued as rs1258438147; called by muse, mutect2
- CLK2P1 | n.743A>T | RNA (SNP) | VAF 130/551 reads (24%) | called by muse, mutect2, varscan2
70 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 70 other) are not listed here.
